Gene-level copy-number profile of tumor specimen TCGA-EE-A29R-06A from TCGA case TCGA-EE-A29R, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 49.4 years (18,028 days).
Specimen TCGA-EE-A29R-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.aa16cdcf-21e3-4d5f-aa2a-508b57865242.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A29R-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cb8bc2b-9743-49ea-b107-c1fa32f64123

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 2: 2,436; copy number 3: 7,988; copy number 4: 21,917; copy number 5: 3,122; copy number 6: 16,489; copy number 7: 2,481; copy number 8: 296; copy number 9: 2,379; copy number 13: 1,628; copy number 14: 1,054.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A29R-06A-11D-A191-01): tumor purity 0.98, ploidy 2.58, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–4): AL359922.1.
- chr9:21,929,457–24,592,104, 28 genes: ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5,061 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–240,698,429, 2,378 genes, copy number 9 (broad region; genes not listed).
- chr2:5,313,740–5,314,134, 1 gene, copy number 9: AC073143.1.
- chr6:167,607–58,438,364, 1,526 genes, copy number 13–14 (within-gene range 8–14) (broad region; genes not listed).
- chr13:27,620,742–114,337,626, 1,156 genes, copy number 13–14 (within-gene range 3–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
